Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6667, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6667-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

FINAL DIAGNOSIS:

[REDACTED]

Aperio

Cells counted : 26,646

© 2006 The Authors
Journal compilation © 2006 Blackwell Publishing Ltd

NEU-N IMMUNOHISTOCHEMICAL STAIN:

POSITIVE STAINING OF NON-NEOPLASTIC CORTICAL NEURONS IN AREA INFILTRATED BY ASTROCYTOMA CELLS.

[page 2 of 3]
Microscopic Description:

The tumor is composed of moderately pleomorphic glial cells. The glial tumor cells infiltrate cerebral grey matter and cortical neurons are present that are surrounded by tumor cells. Many tumor cells show positive immunohistochemical staining for GFAP. No ganglion cell component of the tumor is identified on chromogranin immunohistochemical stain. Many tumor cell nuclei show positive immunohistochemical staining for p53.

The Ki67 proliferation index of this neoplasm is 1.9%.

This infiltrating glial neoplasm is best classified as astrocytoma, WHO grade II.

Frozen Section Diagnosis:

1. Left parietal tumor consistent with glioma: Infiltrating glial neoplasm, oligodendrocyte tumor versus astrocytoma. Frozen section diagnosis by [REDACTED].

Clinical History and Diagnosis:

Left parietal lesion

Source of Specimen:

1: Left parietal tumor consistent with glioma

Gross Description:

1. Left parietal tumor consistent with glioma: Received fresh for frozen labeled with the patient's name and #1 left parietal tumor consistent with glioma is an aggregate of tan-red soft tissue measuring 1.5 x 1.5 x 0.8 cm. Touch preps are prepared. Approximately 70% of the specimen is submitted for frozen section. The remainder is entirely submitted in one additional cassette. This specimen is for rapid processing.

Histology Laboratory

Part 1: Left parietal tumor consistent with glioma

CHROMOGRANIN A

GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)

KI 67 (Aperio)

NEU - N

P 53

[page 3 of 3]
[REDACTED]

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED] et.al. [REDACTED]
[REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.
[REDACTED]
[REDACTED]

EGFR pharmDx [REDACTED] Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.
[REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]
[REDACTED].

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

Source: NCI Genomic Data Commons file d3c89eff-bdeb-4022-95c7-6ba0b8a4bc20 (TCGA-CS-6667.18C7EBD7-0BDC-42E2-97A7-BF8715B01183.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).